Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5514, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5514-01A (Primary Tumor).

PATIENT HISTORY:

The patient has a history of PSA value of 7.4, [REDACTED] right inguinal hernia done in an open fashion with mesh and spinal stenosis. The patient also has a history of biopsy on [REDACTED] this biopsy reveals unilateral poorly differentiated prostatic adenocarcinoma of the right side.

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical retropubic prostatectomy.

TCGA-EJ-5514

FINAL DIAGNOSIS:

PART 1:

LYMPH NODES, RIGHT PELVIC, EXCISION -

NO EVIDENCE OF METASTASIS IN FIVE LYMPH NODES (0/5).

PART 2:

LYMPH NODES, LEFT PELVIC, EXCISION -

NO EVIDENCE OF METASTASIS IN SEVEN LYMPH NODES (0/7).

PART 3:

PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE $4 + 5 = 9$.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.9 cm.
- C. THE CARCINOMA INVOLVES APPROXIMATELY 20% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA IS ORGAN CONFINED AND SHOWS NO EVIDENCE OF EXTRACAPSULAR EXTENSION.
- E. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- F. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- G. PERINEURAL INVASION IS IDENTIFIED.
- H. NO ANGIOLYMPHATIC INVASION IS SEEN.
- I. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE: pT2c N0 Mx.
- K. BENIGN NODULAR HYPERPLASIA AND CHRONIC INFLAMMATION ARE NOTED.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 7.4
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	5
GLEASON SUM SCORE:	9
GLEASON 4/5 PERCENTAGE:	80%
WEIGHT OF PROSTATE:	49.77gm
TUMOR SIZE:	Maximum dimension: 1.9 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	12
LYMPH NODES POSITIVE:	0
EXTRANODAL EXTENSION:	No
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file a4e74813-5c53-484b-9aac-b41e5b744d23 (TCGA-EJ-5514.5B64AD18-513E-422D-A847-D1862DD0E453.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).